Somatic mutation profile of tumor specimen TCGA-04-1644-01B (aliquot TCGA-04-1644-01B-01D-1526-09) from TCGA case TCGA-04-1644, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 48.5 years (17,725 days).
Specimen TCGA-04-1644-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8d656618-a110-42d5-9e3d-b0a6c95ee342.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-04-1644-11A (Solid Tissue Normal), aliquot TCGA-04-1644-11A-01D-1526-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d2251cbe-fddb-4d18-89d7-582e658e857d

The open-access MAF lists 26 somatic variants for this specimen: 25 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 20, Nonsense Mutation 3, Silent 1, Splice Site 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCC8 | c.2635G>C p.D879H | Missense Mutation (SNP) | VAF 214/319 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV56846952, COSV56857515; called by muse, mutect2, varscan2
- AKR1B1 | c.173C>T p.A58V | Missense Mutation (SNP) | VAF 275/748 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.243); catalogued as COSV53648834; called by mutect2, varscan2
- AMD1 | c.21C>A p.F7L | Missense Mutation (SNP) | VAF 111/244 reads (45%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.995); catalogued as COSV64386965, COSV64388249; called by muse, mutect2, varscan2
- CST11 | c.412G>A p.D138N (on ENST00000377009 / NM_130794.2; = p.D103N on NM_080830.3) | Missense Mutation (SNP) | VAF 25/385 reads (6%) | SIFT tolerated (0.3); PolyPhen benign (0.036); catalogued as COSV65440490; called by muse, mutect2
- CTNNA1 | c.361C>T p.R121* | Nonsense Mutation (SNP) | VAF 10/95 reads (11%) | catalogued as COSV57077911; called by muse, mutect2, varscan2
- DCT | c.280A>T p.T94S | Missense Mutation (SNP) | VAF 34/370 reads (9%) | SIFT tolerated (0.25); PolyPhen benign (0.019); catalogued as COSV100986272; called by muse, mutect2
- DDX4 | c.325T>A p.F109I | Missense Mutation (SNP) | VAF 29/68 reads (43%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.983); catalogued as COSV61757285; called by muse, varscan2
- DOCK7 | c.6367G>T p.V2123F (on ENST00000635253 / NM_001367561.1; = p.V2092F on NM_033407.3) | Missense Mutation (SNP) | VAF 72/190 reads (38%) | SIFT tolerated, low confidence (0.72); PolyPhen benign (0.001); catalogued as rs748603618, COSV52020689; called by muse, varscan2
- ITGAL | c.1730G>A p.G577E | Missense Mutation (SNP) | VAF 177/244 reads (73%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.462); catalogued as COSV63324297; called by muse, mutect2, varscan2
- KLF2 | c.1015C>T p.R339C | Missense Mutation (SNP) | VAF 85/194 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1459386855, COSV50180028; called by muse, mutect2, varscan2
- LZTR1 | c.842C>T p.P281L | Missense Mutation (SNP) | VAF 14/106 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs1390048261, CD151200, COSV53147042, COSV53148013; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MFN2 | c.1190G>A p.R397Q | Missense Mutation (SNP) | VAF 79/105 reads (75%) | SIFT tolerated (0.66); PolyPhen benign (0.003); catalogued as rs778219078, COSV52425500; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MSH3 | c.2615G>T p.G872V | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV54143570, COSV54163960; called by mutect2, varscan2
- PDK3 | c.517G>C p.G173R | Missense Mutation (SNP) | VAF 16/276 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.884); catalogued as COSV100998192; called by muse, mutect2
- PNKD | c.985-1G>A p.X329_splice | Splice Site (SNP) | VAF 73/178 reads (41%) | catalogued as COSV51240550; called by muse, mutect2, varscan2
- PRDX5 | c.106G>A p.G36R | Missense Mutation (SNP) | VAF 103/239 reads (43%) | SIFT tolerated (0.26); PolyPhen benign (0.326); catalogued as rs1019065444, COSV50008184; called by mutect2, varscan2
- SH3BGRL | c.151G>T p.E51* | Nonsense Mutation (SNP) | VAF 22/69 reads (32%) | catalogued as COSV64620244; called by muse, mutect2, varscan2
- SKIV2L | c.1632G>C p.Q544H | Missense Mutation (SNP) | VAF 86/252 reads (34%) | SIFT tolerated (0.21); PolyPhen benign (0.169); catalogued as COSV64814087; called by muse, mutect2, varscan2
- SLC4A4 | c.2827C>T p.R943C (on ENST00000264485 / NM_001098484.3; = p.R899C on NM_003759.4) | Missense Mutation (SNP) | VAF 19/24 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52623568; called by muse, varscan2
- THBS2 | c.1175A>T p.Q392L | Missense Mutation (SNP) | VAF 144/323 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.049); catalogued as COSV64682141; called by muse, mutect2, varscan2
- VPS35L | c.304C>T p.R102C | Missense Mutation (SNP) | VAF 32/78 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.401); catalogued as rs570834372, COSV51990149; called by muse, mutect2, varscan2
- CLVS1 | c.443G>T p.W148L | Missense Mutation (SNP) | VAF 2/16 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2
- CYFIP1 | c.1938G>A p.W646* | Nonsense Mutation (SNP) | VAF 141/375 reads (38%) | called by muse, mutect2, varscan2
- KIFAP3 | c.1693G>C p.V565L | Missense Mutation (SNP) | VAF 6/114 reads (5%) | SIFT tolerated (0.19); PolyPhen benign (0.109); called by muse, mutect2
- REST | c.866dup p.N289Kfs*8 | Frame Shift Ins (INS) | VAF 6/10 reads (60%) | called by mutect2, varscan2
- GLMN | c.381G>A p.Q127= | Silent (SNP) | VAF 20/55 reads (36%) | catalogued as COSV64861630; called by muse, mutect2, varscan2
